Gene-level copy-number profile of tumor specimen C3N-00733-01 from CPTAC case C3N-00733, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 56.1 years (20,507 days).
Specimen C3N-00733-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file efe32cef-6f85-40ca-bdd6-c86676af947c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00733-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/022cfd1a-beb0-491a-a893-b526aadb4ad7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 7,366; copy number 2: 40,811; copy number 3: 8,593; copy number 4: 2,111; copy number 5: 7; copy number 6: 3; copy number 11: 5.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,330,717–61,627,683, 4 genes: CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr15:28,679,405–28,682,252, 1 gene (within-gene range 0–2): AC055876.2.
- chr15:28,703,554–28,703,790, 1 gene (within-gene range 0–2): RN7SL719P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–71,585, 8 genes, copy number 6–11: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, OR4G4P, OR4G11P, OR4F5.
- chr16:11,555–53,608, 7 genes, copy number 5 (within-gene range 3–5): DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K.

Autosomal genes at a single copy (total copy number 1): 4,532. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
